Gene-level copy-number profile of tumor specimen C3L-07981-04 from CPTAC case C3L-07981, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 68.9 years (25,157 days).
Specimen C3L-07981-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9175c08b-7975-4425-86d6-05d950987cee.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-07981-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,747 have no estimate.
https://portal.gdc.cancer.gov/files/b9da1427-41d2-4644-98c4-e01f9e1b6a3a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 62; copy number 1: 1,142; copy number 2: 2,738; copy number 3: 9,725; copy number 4: 34,985; copy number 5: 8,914; copy number 6: 785; copy number 7: 156; copy number 8: 51; copy number 9: 210; copy number 10: 43; copy number 11: 62; copy number 15: 3.

Homozygous deletions (total copy number 0; autosomes only): 52 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,132,927–3,208,664, 2 genes (within-gene range 0–2): AL008733.1, AL512383.1.
- chr1:97,394,154–97,420,141, 1 gene (within-gene range 0–3): DPYD-IT1.
- chr1:174,849,667–174,954,261, 5 genes (within-gene range 0–2): NDUFAF4P4, Z99127.2, RABGAP1L-IT1, Z99127.1, RABGAP1L-AS1.
- chr1:204,422,628–204,494,724, 1 gene (within-gene range 0–5): PIK3C2B.
- chr2:28,384,409–28,394,672, 1 gene (within-gene range 0–4): FLJ31356.
- chr3:42,051,181–42,051,694, 1 gene (within-gene range 0–2): AC093414.1.
- chr3:60,616,822–60,618,079, 2 genes (within-gene range 0–2): AC104164.2, MIR548BB.
- chr3:175,059,361–175,115,242, 2 genes (within-gene range 0–2): EEF1B2P8, NAALADL2-AS3.
- chr4:90,838,903–91,112,790, 2 genes (within-gene range 0–2): TMSB4XP8, AC004054.1.
- chr5:59,314,110–59,314,800, 1 gene (within-gene range 0–2): AC008833.1.
- chr5:60,021,249–60,033,020, 1 gene (within-gene range 0–2): AC034234.1.
- chr6:1,601,654–2,245,605, 4 genes: FOXCUT, FOXC1, GMDS, AL035693.1.
- chr7:158,027,373–158,031,128, 1 gene (within-gene range 0–3): AC011899.1.
- chr9:15,524,576–15,544,294, 4 genes: AL513423.1, RN7SL98P, FTH1P12, RNU6-246P.
- chr9:15,588,355–15,588,615, 1 gene (within-gene range 0–2): HMGN2P16.
- chr11:1,012,823–1,055,749, 2 genes: MUC6, LINC02688.
- chr11:63,998,558–64,223,891, 7 genes (within-gene range 0–4): MACROD1, AP000721.2, AP006333.2, FLRT1, AP006333.1, STIP1, FERMT3.
- chr11:68,312,591–68,449,275, 1 gene: LRP5.
- chr16:78,355,529–78,355,834, 1 gene (within-gene range 0–2): LSM3P5.
- chr16:78,825,281–78,826,006, 1 gene (within-gene range 0–2): RPS3P7.
- chr17:82,101,460–82,212,830, 3 genes: CCDC57, AC129510.1, AC129510.2.
- chr19:1,107,637–1,228,431, 3 genes (within-gene range 0–2): SBNO2, STK11, HMGB2P1.
- chr19:13,862,063–13,930,879, 5 genes: NANOS3, MIR181C, MIR181D, C19orf57, CC2D1A.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 318 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,363,091–152,601,086, 117 genes, copy number 9 (broad region; genes not listed).
- chr14:18,333,726–18,419,273, 4 genes, copy number 9: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr18:8,406,761–9,619,363, 32 genes, copy number 9 (within-gene range 5–9): AP001094.1, COP1P1, RN7SL50P, THEMIS3P, AKR1B1P6, RAB12, AP001793.1, TOMM20P3, GACAT2, MTCL1, Y_RNA, AP000864.1, RPS4XP19, NDUFV2, AP005263.1, AP005899.1, NDUFV2-AS1, ANKRD12, Y_RNA, Y_RNA, AP001033.2, AP001033.1, TWSG1, AP001033.3, AP005432.2, RALBP1, AP005432.1, RNU2-27P, PPP4R1, AP001381.1, PPP4R1-AS1, RNU6-903P.
- chr18:11,689,264–12,658,134, 43 genes, copy number 10 (within-gene range 8–10): GNAL, ASNSP6, AP001120.5, AP005137.1, CHMP1B, CHMP1B-AS1, AP005137.2, MPPE1, AP001269.4, AP001269.2, AP001269.3, IMPA2, AP001269.1, AP001542.3, AP001542.1, AP001542.2, AP002414.1, AP002414.4, AP002414.2, AP002414.5, AP002414.3, ANKRD62, RNU6-324P, SDHDP1, PMM2P2, AP005264.5, AP005264.3, AP005264.4, CCDC58P3, AP005264.2, PPIAP56, CIDEA, AP005264.6, AP005264.1, RNU6-170P, TUBB6, AFG3L2, RNU7-129P, PRELID3A, AP001029.1, AP001029.2, SPIRE1, AP001029.3.
- chr18:12,738,965–21,241,371, 90 genes, copy number 9–15 (broad region; genes not listed).
- chr18:23,134,564–24,453,531, 32 genes, copy number 9: CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR, AC090772.3, OSBPL1A, RNA5SP452, Metazoa_SRP, RNU6-435P, MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2.

Autosomal genes at a single copy (total copy number 1): 188. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
